Somatic mutation profile of tumor specimen C3L-02112-02 (aliquot CPT0124410007_1) from CPTAC case C3L-02112, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.0 years (24,455 days).
Specimen C3L-02112-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b44667d-dab4-4932-a4a8-b94489c1d613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02112-31 (Blood Derived Normal), aliquot CPT0124440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94069bdc-3dc1-4cc7-8813-f53eaa6abdf7

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Splice Region 2, Intron 2, Nonsense Mutation 2, Splice Site 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-2A>G p.X153_splice | Splice Site (SNP) | VAF 23/715 reads (3%) | hotspot (GDC flag); catalogued as CS127045, CS1414343, COSV58683256, COSV58703271, COSV58726067; called by muse, mutect2
- GALE | c.873+3A>G | Splice Region (SNP) | VAF 23/636 reads (4%) | catalogued as rs1340981893; called by muse, mutect2
- SETD2 | c.5236G>T p.E1746* | Nonsense Mutation (SNP) | VAF 18/448 reads (4%) | catalogued as COSV57430307; called by muse, mutect2
- SLITRK1 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV65674607, COSV65675334; called by muse, mutect2
- ABL2 | c.541A>G p.S181G (on ENST00000502732 / NM_007314.4; = p.S166G on NM_005158.5) | Missense Mutation (SNP) | VAF 34/726 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2
- GSK3A | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGLV8-61 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 16/566 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- KDM5C | c.4279C>T p.Q1427* | Nonsense Mutation (SNP) | VAF 21/421 reads (5%) | called by muse, mutect2
- MICU3 | c.984G>A p.E328= | Splice Region (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- SMAD4 | c.213T>G p.C71W | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STAB1 | c.450C>G p.C150W | Missense Mutation (SNP) | VAF 24/812 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFHX2 | c.303A>G p.E101= | Silent (SNP) | VAF 10/293 reads (3%) | catalogued as rs1169039616; called by muse, mutect2
- ITGA9 | c.1839+63G>T | Intron (SNP) | VAF 20/620 reads (3%) | catalogued as COSV53247220; called by muse, mutect2
- SYMPK | c.3082-10C>T | Intron (SNP) | VAF 12/382 reads (3%) | catalogued as rs1277042109; called by muse, mutect2
- VPS35L | chr16:19555496 C>T | 5'Flank (SNP) | VAF 14/313 reads (4%) | catalogued as rs1469283810; called by muse, mutect2
